Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3891, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3891-01A (Primary Tumor).

Diagnosis:

This is a resection sample from the sigmoid colon/rectum with a segmental diverticulosis in the sigmoid colon part of the resection material with a moderately differentiated adenocarcinoma in the rectum with a histopathological differentiation grade G2, with erosions of the inner tumor surface, with tumor infiltration of the rectum wall layers as far as the tunica muscularis, with carcinomatous lymphangitis, with focal extracellular mucus formation, with peritumorous chronic recurrent secondary inflammation with an acute inflammatory flare, with tumor-free lymph nodes (0/13) with moderate chronic lymphadenitis with focal lipomatous atrophy and tumor-free overview slices from all other parts of the resection material described.

According to the section preparations available, the tumor spread of the rectal carcinoma corresponds to the tumor stage pT2, pN0 (0/13), MX, L1, R0

Tumor classification:

ICDO-DA M-8140/3

G2

Source: NCI Genomic Data Commons file 0d9ee9a6-d0fc-4ec8-b061-b9394a0da75f (TCGA-AG-3891.64AFBB41-D8F4-4980-AB85-E2E893E188F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).